Somatic mutation profile of tumor specimen ALCH-AFEE-TTP1-A (aliquot ALCH-AFEE-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AFEE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,347 days).
Specimen ALCH-AFEE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 621ca237-f779-43e2-b0e2-7f233abd34fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFEE-NB1-A (Blood Derived Normal), aliquot ALCH-AFEE-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68dac223-df66-4319-9057-9993d99f6675

The open-access MAF lists 90 somatic variants for this specimen: 55 protein-altering or splice-affecting, 19 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Intron 9, RNA 5, Nonsense Mutation 4, Splice Site 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 46/386 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM8 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs1468400617; called by muse, mutect2
- ARHGEF6 | c.1830G>T p.E610D | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.638); catalogued as COSV51694645; called by muse, mutect2, varscan2
- B4GALNT1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs1252076628; called by muse, mutect2
- CACNA2D1 | c.3195G>T p.L1065F (on ENST00000356253 / NM_001366867.1; = p.L1053F on NM_000722.4) | Missense Mutation (SNP) | VAF 19/408 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV62394507; called by muse, mutect2
- CCDC74B | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs751794865; called by muse, mutect2
- INSRR | c.1678G>T p.V560L | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.437); catalogued as COSV63877568; called by muse, mutect2, varscan2
- LRP5 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV53715013; called by muse, mutect2
- N4BP2L2 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 31/293 reads (11%) | catalogued as rs201113250, COSV57228050; called by muse, mutect2, varscan2
- SCX | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.236); catalogued as rs1288599259; called by muse, mutect2
- SH3TC2 | c.1678G>T p.G560* | Nonsense Mutation (SNP) | VAF 30/280 reads (11%) | catalogued as rs1279803181; called by muse, mutect2
- SPTA1 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 42/539 reads (8%) | catalogued as rs1440718209; called by muse, mutect2
- STX5 | c.629A>T p.Q210L | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV53678602; called by muse, mutect2, varscan2
- TEKT3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as rs147750959; called by muse, mutect2, varscan2
- THBS2 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1477536579; called by muse, varscan2
- TMEM158 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1324908543, COSV100281505; called by muse, mutect2, varscan2
- ABCC8 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.193); called by muse, mutect2
- ADAMTSL3 | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 45/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADD2 | c.2138C>A p.S713Y | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ARHGAP24 | c.1258G>T p.V420F (on ENST00000395184 / NM_001025616.3; = p.V327F on NM_031305.3) | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); called by muse, mutect2
- BARX1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAT | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2
- DLEC1 | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2
- DNAH12 | c.7277G>C p.S2426T (on ENST00000351747; = p.S3294T on NM_001366028.2) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, varscan2
- DOCK4 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- EXT2 | c.85C>T p.L29F (on ENST00000343631; = p.L62F on NM_000401.3) | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- GABBR1 | c.1117A>G p.K373E | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GABRB2 | c.1358G>C p.R453P (on ENST00000274547; = p.R415P on NM_000813.3) | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.273); called by muse, mutect2
- GABRG2 | c.327+1G>T p.X109_splice | Splice Site (SNP) | VAF 28/376 reads (7%) | called by muse, mutect2
- GABRQ | c.1322A>T p.Q441L | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- KAT14 | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2
- LCTL | c.693C>G p.H231Q | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LGR6 | c.365A>G p.Q122R (on ENST00000367278 / NM_001017403.1; = p.Q70R on NM_021636.3) | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPIN2 | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.104); called by muse, mutect2
- LRP8 | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NAE1 | c.1033G>T p.V345F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- NEU2 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHS | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- NLGN4X | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOTCH3 | c.1164T>G p.C388W | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPY2R | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PARP11 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- PCDHA7 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 32/594 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2
- POLG2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- POLQ | c.1589G>T p.S530I | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PON3 | c.474A>G p.I158M | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2
- RASSF2 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RBM3 | c.210+1G>T p.X70_splice | Splice Site (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- ROBO2 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 42/429 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SMARCA4 | c.2808C>A p.C936* | Nonsense Mutation (SNP) | VAF 22/309 reads (7%) | called by muse, mutect2
- SRPX2 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 54/686 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D30 | c.764G>A p.R255K (on ENST00000542120; = p.R92K on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- TGFBRAP1 | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); called by muse, mutect2
- TMEM132C | c.3130C>A p.L1044M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); called by muse, mutect2
- TOGARAM1 | c.1636A>G p.T546A | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ADD2 | c.2136C>A p.P712= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV52465341; called by muse, mutect2
- ADGRD1 | c.606A>G p.G202= | Silent (SNP) | VAF 42/648 reads (6%) | called by muse, mutect2
- ANGPT4 | c.342G>A p.S114= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as rs943789944, COSV101124867; called by muse, mutect2
- APOD | c.405C>A p.T135= | Silent (SNP) | VAF 23/325 reads (7%) | called by muse, mutect2
- CCDC74B | c.600C>T p.V200= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as rs767528851; called by muse, mutect2
- CEP170 | c.1338A>C p.S446= | Silent (SNP) | VAF 34/356 reads (10%) | called by muse, mutect2
- GJB5 | c.183C>A p.S61= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- GPR143 | c.1062G>A p.G354= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- HBB | c.273G>A p.E91= | Silent (SNP) | VAF 40/393 reads (10%) | catalogued as CD149816, CM016215; called by muse, mutect2, varscan2
- HDAC8 | c.600G>C p.L200= | Silent (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- HNF4A | c.255G>T p.R85= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- LRP1B | c.2883T>A p.S961= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- MUC16 | c.41520T>A p.S13840= | Silent (SNP) | VAF 19/276 reads (7%) | called by muse, mutect2
- OR13H1 | c.357C>A p.A119= | Silent (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- OR2B2 | c.855G>A p.L285= | Silent (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- OR2G2 | c.723C>T p.F241= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs765219287, COSV60740172; called by muse, mutect2
- PTPRN | c.2118G>T p.R706= | Silent (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- TCEAL1 | c.234G>T p.L78= | Silent (SNP) | VAF 12/197 reads (6%) | called by muse, mutect2
- TLL1 | c.1296T>C p.L432= | Silent (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- ABCG5 | c.144-40G>A | Intron (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- CDK4 | c.218+33G>T | Intron (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
- CYP2B7P | n.61C>A | RNA (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2
- ERG | c.766+100C>A | Intron (SNP) | VAF 26/381 reads (7%) | called by muse, mutect2
- GDPD2 | c.1307+1041C>A | Intron (SNP) | VAF 13/205 reads (6%) | called by muse, mutect2
- HHLA3 | n.521C>G | RNA (SNP) | VAF 13/201 reads (6%) | called by muse, mutect2
- IGLV1-44 | c.-11C>A | 5'UTR (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2
- KIF28P | n.2719-31C>T | Intron (SNP) | VAF 30/256 reads (12%) | catalogued as rs561181330; called by muse, mutect2
- LINC02118 | n.100G>T | RNA (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- MIR892B | n.62G>T | RNA (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- NCF1B | n.159-1459C>A | Intron (SNP) | VAF 25/457 reads (5%) | called by muse, mutect2
- NELFE | c.942+14A>T | Intron (SNP) | VAF 34/265 reads (13%) | called by muse, mutect2, varscan2
- NSG2 | c.*150G>T | 3'UTR (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- SEL1L | c.891+25A>G | Intron (SNP) | VAF 6/75 reads (8%) | catalogued as COSV60922553; called by muse, mutect2
- SNORD115-9 | n.62A>T | RNA (SNP) | VAF 26/410 reads (6%) | called by muse, mutect2
- TTLL9 | c.706-118G>A | Intron (SNP) | VAF 32/268 reads (12%) | catalogued as rs1042295222; called by muse, varscan2
